Somatic mutation profile of tumor specimen C3L-07981-04 (aliquot CPT0481050006) from CPTAC case C3L-07981, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 68.9 years (25,157 days).
Specimen C3L-07981-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 90c2ddd5-1308-4bf5-a08e-3696c5ae3f4d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-07981-31 (Blood Derived Normal), aliquot CPT0481170003; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/98ad49bd-89f0-44e3-bd17-c7c03bf7010d

The open-access MAF lists 387 somatic variants for this specimen: 290 protein-altering or splice-affecting, 82 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 270, Silent 82, Intron 10, Nonsense Mutation 9, Frame Shift Ins 4, Splice Region 2, Frame Shift Del 2, 3'UTR 2, RNA 1, Nonstop Mutation 1, 5'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA4 | c.2827C>T p.R943W | Missense Mutation (SNP) | VAF 123/394 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.654); catalogued as rs61749446, CD033153, CM990034; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ASXL3 | c.4399C>T p.R1467* | Nonsense Mutation (SNP) | VAF 88/306 reads (29%) | catalogued as rs1204482456; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCB11 | c.985G>A p.V329M | Missense Mutation (SNP) | VAF 104/364 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.009); catalogued as rs1031565435; called by muse, mutect2, varscan2
- ABCB5 | c.1706A>T p.K569M (on ENST00000404938 / NM_001163941.2; = p.K124M on NM_178559.6) | Missense Mutation (SNP) | VAF 10/272 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99327347; called by muse, mutect2
- ACSM2A | c.18A>C p.K6N | Missense Mutation (SNP) | VAF 60/252 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.466); catalogued as rs752798612; called by muse, mutect2
- ACYP1 | c.5C>G p.P2R | Missense Mutation (SNP) | VAF 45/422 reads (11%) | SIFT deleterious, low confidence (0); catalogued as rs964865222; called by muse, mutect2
- ADAMTS16 | c.950C>T p.T317M | Missense Mutation (SNP) | VAF 73/204 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746490045, COSV57008084; called by muse, mutect2, varscan2
- ADAMTS18 | c.1736A>C p.K579T | Missense Mutation (SNP) | VAF 104/333 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.254); catalogued as rs569546410; called by muse, mutect2, varscan2
- AKAP6 | c.6203C>T p.S2068L | Missense Mutation (SNP) | VAF 90/352 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs772533351, COSV55205772; called by muse, mutect2, varscan2
- ANK3 | c.10021G>A p.D3341N | Missense Mutation (SNP) | VAF 56/390 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs765213109, COSV55055688, COSV55069067; called by muse, mutect2, varscan2
- ANKEF1 | c.62G>A p.R21Q | Missense Mutation (SNP) | VAF 51/380 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.141); catalogued as rs760875632, COSV101001007; called by muse, mutect2, varscan2
- ANKZF1 | c.1963C>T p.R655* | Nonsense Mutation (SNP) | VAF 44/278 reads (16%) | catalogued as rs1473207265; called by mutect2, varscan2
- AP5Z1 | c.1717G>A p.G573R | Missense Mutation (SNP) | VAF 77/423 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.428); catalogued as rs746432998; called by muse, mutect2, varscan2
- AR | c.2179C>T p.R727C | Missense Mutation (SNP) | VAF 42/183 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781301298, COSV65962818; called by muse, mutect2, varscan2
- ATP10A | c.596A>G p.N199S | Missense Mutation (SNP) | VAF 49/388 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.377); catalogued as rs762118896; called by muse, mutect2, varscan2
- C1QTNF9 | c.206C>T p.T69M | Missense Mutation (SNP) | VAF 96/680 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs780428044; called by muse, mutect2, varscan2
- C8B | c.1279G>C p.V427L | Missense Mutation (SNP) | VAF 50/289 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.668); catalogued as rs1557730898; called by muse, mutect2, varscan2
- CACNA2D3 | c.1247G>A p.G416E | Missense Mutation (SNP) | VAF 39/160 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55515765; called by muse, mutect2, varscan2
- CCDC178 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 11/91 reads (12%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.103); catalogued as COSV100283157; called by muse, mutect2, varscan2
- CDH22 | c.1685C>T p.T562M | Missense Mutation (SNP) | VAF 91/350 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.409); catalogued as rs760770308, COSV64837323; called by muse, mutect2, varscan2
- CDH8 | c.281A>T p.K94I | Missense Mutation (SNP) | VAF 74/250 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.139); catalogued as COSV54885169; called by muse, varscan2
- CDHR3 | c.10G>T p.A4S | Missense Mutation (SNP) | VAF 18/497 reads (4%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV58416875; called by muse, mutect2
- CFAP161 | c.113T>G p.L38R | Missense Mutation (SNP) | VAF 50/239 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99715641; called by muse, mutect2, varscan2
- CFH | c.71T>C p.L24P | Missense Mutation (SNP) | VAF 57/206 reads (28%) | SIFT tolerated (0.54); PolyPhen benign (0.012); catalogued as rs1007759235, COSV62778925; called by muse, mutect2, varscan2
- CIC | c.1018C>T p.R340W | Missense Mutation (SNP) | VAF 137/445 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as rs759240445, COSV50635011; called by muse, mutect2, varscan2
- CLUAP1 | c.83G>A p.R28H | Missense Mutation (SNP) | VAF 81/309 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.284); catalogued as rs754881174; called by muse, mutect2, varscan2
- CNTNAP5 | c.1880A>C p.K627T | Missense Mutation (SNP) | VAF 54/237 reads (23%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.995); catalogued as COSV101444355; called by muse, mutect2, varscan2
- COL16A1 | c.118C>T p.H40Y | Missense Mutation (SNP) | VAF 87/341 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs755172487; called by muse, mutect2, varscan2
- COL1A1 | c.1450C>T p.P484S | Missense Mutation (SNP) | VAF 117/382 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.075); catalogued as rs879355791; called by muse, mutect2, varscan2
- COL22A1 | c.419G>A p.R140H | Missense Mutation (SNP) | VAF 206/559 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.916); catalogued as COSV104407857; called by muse, mutect2, varscan2
- CYLC1 | c.1247A>G p.K416R | Missense Mutation (SNP) | VAF 36/111 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as COSV100255599; called by muse, mutect2, varscan2
- DCT | c.625T>G p.F209V | Missense Mutation (SNP) | VAF 65/276 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV65470377; called by muse, mutect2, varscan2
- DHX38 | c.751C>T p.R251* | Nonsense Mutation (SNP) | VAF 16/337 reads (5%) | catalogued as COSV51697928; called by muse, mutect2
- DISP3 | c.3598G>A p.V1200M | Missense Mutation (SNP) | VAF 104/420 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as rs369603181; called by muse, mutect2, varscan2
- DLG2 | c.165T>G p.F55L (on ENST00000650630 / NM_001351274.2; = p.F18L on NM_001142699.3) | Missense Mutation (SNP) | VAF 21/143 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV65821881, COSV65833079; called by muse, mutect2, varscan2
- DNAH8 | c.12191G>A p.R4064Q | Missense Mutation (SNP) | VAF 35/216 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1327466194, COSV59421605; called by muse, mutect2, varscan2
- DNER | c.1414T>G p.C472G | Missense Mutation (SNP) | VAF 103/399 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV100518761; called by muse, mutect2, varscan2
- DOCK2 | c.3059A>C p.N1020T | Missense Mutation (SNP) | VAF 33/209 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV56939865, COSV56981500; called by muse, mutect2, varscan2
- DSPP | c.207A>T p.Q69H | Missense Mutation (SNP) | VAF 87/327 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); catalogued as rs1352401738, COSV56807373, COSV99217614; called by muse, mutect2, varscan2
- DST | c.14505G>A p.E4835= (on ENST00000361203 / NM_001374722.1; = p.E2423= on NM_015548.5) | Splice Region (SNP) | VAF 14/212 reads (7%) | catalogued as rs1218645978; called by muse, mutect2
- EGFR | c.3409G>A p.E1137K | Missense Mutation (SNP) | VAF 108/529 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.57); catalogued as rs780967013, COSV51832266, COSV51859204; called by muse, mutect2, varscan2
- EP400 | c.1532C>T p.P511L | Missense Mutation (SNP) | VAF 30/320 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs200859619; called by muse, mutect2
- ESPL1 | c.4756C>T p.R1586W | Missense Mutation (SNP) | VAF 100/358 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); catalogued as COSV99228675; called by muse, mutect2, varscan2
- F2RL3 | c.293C>T p.A98V | Missense Mutation (SNP) | VAF 170/524 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777444551; called by mutect2, varscan2
- FAM171B | c.1862G>T p.S621I | Missense Mutation (SNP) | VAF 98/368 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.767); catalogued as COSV59004493; called by mutect2, varscan2
- FAM181B | c.1022G>A p.R341H | Missense Mutation (SNP) | VAF 126/566 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.674); catalogued as COSV61300654; called by muse, varscan2
- FAT4 | c.3185T>G p.L1062R | Missense Mutation (SNP) | VAF 103/359 reads (29%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.998); catalogued as COSV67885321; called by muse, mutect2, varscan2
- FBXL7 | c.1439G>A p.R480H | Missense Mutation (SNP) | VAF 45/292 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs767178690, COSV61654436; called by muse, mutect2, varscan2
- FRMPD4 | c.338A>C p.K113T | Missense Mutation (SNP) | VAF 38/112 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs777067245; called by muse, mutect2, varscan2
- FYB2 | c.1307A>G p.K436R | Missense Mutation (SNP) | VAF 32/360 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.121); catalogued as rs1043203637, COSV58583421; called by muse, mutect2
- GALNT14 | c.526C>T p.R176W | Missense Mutation (SNP) | VAF 70/287 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777768523, COSV61102293; called by muse, mutect2, varscan2
- GEN1 | c.2163G>T p.K721N | Missense Mutation (SNP) | VAF 54/245 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV99060067; called by muse, mutect2, varscan2
- GIMAP8 | c.572C>T p.S191F | Missense Mutation (SNP) | VAF 88/413 reads (21%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as COSV56230851; called by muse, mutect2, varscan2
- GPR63 | c.749C>G p.S250C | Missense Mutation (SNP) | VAF 69/363 reads (19%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.667); catalogued as COSV57739374; called by muse, mutect2, varscan2
- GRM5 | c.25G>A p.V9I | Missense Mutation (SNP) | VAF 58/233 reads (25%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs778784135; called by muse, mutect2, varscan2
- GTPBP2 | c.1366G>A p.V456I | Missense Mutation (SNP) | VAF 50/413 reads (12%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs1369094425; called by muse, mutect2, varscan2
- GUCY2C | c.2016G>T p.E672D | Missense Mutation (SNP) | VAF 35/320 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53796029; called by muse, mutect2, varscan2
- GYPE | c.161C>T p.A54V | Missense Mutation (SNP) | VAF 54/188 reads (29%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs763843605, COSV62261401; called by muse, mutect2, varscan2
- H3C13 | c.116C>T p.P39L | Missense Mutation (SNP) | VAF 16/634 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.109); catalogued as rs1553754959; called by muse, mutect2
- HDHD5 | c.64C>T p.R22C | Missense Mutation (SNP) | VAF 98/251 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs1568954158; called by muse, mutect2, varscan2
- HDX | c.1999G>T p.A667S | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.055); catalogued as rs761470481; called by muse, mutect2, varscan2
- HECW1 | c.653A>C p.K218T | Missense Mutation (SNP) | VAF 30/278 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67827716; called by muse, mutect2, varscan2
- ICAM1 | c.1100G>A p.R367H | Missense Mutation (SNP) | VAF 131/504 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs146000551; called by muse, mutect2, varscan2
- IGKV3-15 | c.303A>C p.E101D | Missense Mutation (SNP) | VAF 82/638 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.246); catalogued as rs762102539; called by muse, mutect2, varscan2
- IGKV3-7 | c.310T>G p.F104V | Missense Mutation (SNP) | VAF 44/314 reads (14%) | SIFT tolerated (0.88); PolyPhen benign (0.003); catalogued as rs775625218; called by muse, mutect2
- IWS1 | c.2074C>T p.L692F | Missense Mutation (SNP) | VAF 63/257 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.372); catalogued as rs1282759334; called by muse, mutect2, varscan2
- JPH1 | c.979G>A p.E327K | Missense Mutation (SNP) | VAF 28/442 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV60609266; called by muse, mutect2
- KIAA0408 | c.2085A>C p.*695Yext*57 | Nonstop Mutation (SNP) | VAF 68/193 reads (35%) | catalogued as rs1324609030; called by muse, mutect2, varscan2
- KLHDC7B | c.1495G>A p.D499N (on ENST00000395676; = p.D1140N on NM_138433.5) | Missense Mutation (SNP) | VAF 69/302 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs750240598, COSV67465373; called by muse, mutect2
- KRIT1 | c.419G>A p.R140Q | Missense Mutation (SNP) | VAF 28/289 reads (10%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.945); catalogued as COSV60669227; called by muse, mutect2
- LARP1B | c.2720C>T p.P907L | Missense Mutation (SNP) | VAF 27/349 reads (8%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.011); catalogued as rs779136300, COSV52795595; called by muse, mutect2
- LRP1B | c.11110G>A p.D3704N | Missense Mutation (SNP) | VAF 9/288 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67221388; called by muse, mutect2
- MCM5 | c.1538G>A p.R513H | Missense Mutation (SNP) | VAF 41/287 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99331436; called by muse, mutect2, varscan2
- MN1 | c.1055C>A p.P352H | Missense Mutation (SNP) | VAF 87/525 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.971); catalogued as COSV56556217; called by muse, varscan2
- MTLN | c.386C>T p.A129V | Missense Mutation (SNP) | VAF 78/255 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.794); catalogued as rs974085577; called by muse, mutect2, varscan2
- MUC16 | c.21790A>T p.S7264C | Missense Mutation (SNP) | VAF 88/331 reads (27%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.132); catalogued as COSV67461958; called by muse, mutect2, varscan2
- MYO5C | c.2737A>G p.T913A | Missense Mutation (SNP) | VAF 100/318 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.017); catalogued as rs1418953860; called by muse, mutect2, varscan2
- MYPN | c.2629C>T p.R877C | Missense Mutation (SNP) | VAF 183/404 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.483); catalogued as rs764042082, COSV62735955; called by muse, mutect2, varscan2
- NAV1 | c.4327T>C p.F1443L | Missense Mutation (SNP) | VAF 73/225 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1226053358; called by muse, mutect2, varscan2
- NLRP11 | c.1799G>A p.R600H | Missense Mutation (SNP) | VAF 96/302 reads (32%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as rs375975641; called by muse, mutect2, varscan2
- NOX5 | c.1309G>A p.G437R | Missense Mutation (SNP) | VAF 108/364 reads (30%) | SIFT tolerated (0.56); PolyPhen benign (0.033); catalogued as rs564148426; called by muse, mutect2, varscan2
- OBSCN | c.7373C>T p.S2458F | Missense Mutation (SNP) | VAF 54/370 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs764974541; called by muse, mutect2, varscan2
- OPCML | c.481G>C p.G161R | Missense Mutation (SNP) | VAF 100/320 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100105444; called by muse, mutect2, varscan2
- OR10J1 | c.238A>G p.R80G | Missense Mutation (SNP) | VAF 83/348 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.049); catalogued as rs1398140982, COSV101420085, COSV71129779; called by muse, mutect2, varscan2
- OR6P1 | c.310T>C p.F104L | Missense Mutation (SNP) | VAF 93/342 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV100583471; called by muse, mutect2, varscan2
- OTOGL | c.7050C>A p.C2350* (on ENST00000547103; = p.C2341* on NM_173591.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 12/192 reads (6%) | catalogued as rs1323082156; called by muse, mutect2
- OXTR | c.16G>A p.A6T | Missense Mutation (SNP) | VAF 57/236 reads (24%) | SIFT tolerated (0.43); PolyPhen benign (0.012); catalogued as rs1406481579; called by muse, mutect2, varscan2
- PADI4 | c.1813G>A p.V605I | Missense Mutation (SNP) | VAF 50/203 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs752032759, COSV64923993; called by muse, mutect2, varscan2
- PCDHA1 | c.1700C>T p.A567V | Missense Mutation (SNP) | VAF 154/455 reads (34%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); catalogued as rs368549830; called by muse, mutect2, varscan2
- PCDHB7 | c.1198T>G p.F400V | Missense Mutation (SNP) | VAF 67/266 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.794); catalogued as rs1554280131, COSV50756008; called by muse, mutect2, varscan2
- PCNT | c.6142G>A p.G2048S | Missense Mutation (SNP) | VAF 80/201 reads (40%) | SIFT tolerated (0.81); PolyPhen benign (0.001); catalogued as rs372803743; called by muse, mutect2, varscan2
- PEG3 | c.2042A>C p.K681T | Missense Mutation (SNP) | VAF 119/376 reads (32%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.747); catalogued as COSV55639607; called by muse, mutect2, varscan2
- PGR | c.1844G>A p.R615H | Missense Mutation (SNP) | VAF 81/334 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs778032418, COSV99678942; called by muse, mutect2, varscan2
- PIK3CG | c.1079A>G p.K360R | Missense Mutation (SNP) | VAF 112/488 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV63250883; called by muse, mutect2, varscan2
- POLR1A | c.1819G>A p.E607K | Missense Mutation (SNP) | VAF 91/356 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1447759486, COSV55697594; called by muse, varscan2
- PRG2 | c.580G>A p.G194S | Missense Mutation (SNP) | VAF 86/299 reads (29%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.51); catalogued as rs770219435, COSV61294271; called by muse, mutect2, varscan2
- PRR5L | c.1060A>G p.R354G | Missense Mutation (SNP) | VAF 47/498 reads (9%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0); catalogued as rs1321536457; called by muse, mutect2
- PSG1 | c.830G>T p.G277V | Missense Mutation (SNP) | VAF 126/518 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV99741829; called by muse, mutect2, varscan2
- PTPRT | c.2176G>A p.G726S | Missense Mutation (SNP) | VAF 36/229 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.698); catalogued as rs774983998; called by muse, varscan2
- RAB27B | c.651delinsTT p.C218Lfs*6 | Frame Shift Ins (INS) | VAF 19/230 reads (8%) | catalogued as COSV100024257; called by mutect2*, pindel
- RBM20 | c.441C>A p.H147Q | Missense Mutation (SNP) | VAF 57/499 reads (11%) | SIFT tolerated (0.68); PolyPhen benign (0.275); catalogued as rs397516619; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RGS18 | c.214G>A p.E72K | Missense Mutation (SNP) | VAF 78/255 reads (31%) | SIFT tolerated (0.87); PolyPhen benign (0.011); catalogued as COSV66507874; called by muse, mutect2, varscan2
- RIMKLB | c.543C>G p.S181R | Missense Mutation (SNP) | VAF 97/354 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.048); catalogued as COSV55236146; called by muse, mutect2, varscan2
- RNF157 | c.947G>A p.R316Q | Missense Mutation (SNP) | VAF 60/249 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1357895138; called by muse, mutect2, varscan2
- RNF217 | c.1120C>T p.Q374* (on ENST00000521654 / NM_001286398.2; = p.Q82* on NM_152553.5) | Nonsense Mutation (SNP) | VAF 21/177 reads (12%) | catalogued as COSV51577940; called by muse, mutect2, varscan2
- RNPC3 | c.1244C>G p.P415R | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); catalogued as rs943636615; called by muse, mutect2, varscan2
- ROR2 | c.565C>T p.R189W | Missense Mutation (SNP) | VAF 90/292 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as rs199975149, CM002098; called by muse, mutect2, varscan2
- RUBCNL | c.1306G>A p.G436S | Missense Mutation (SNP) | VAF 52/317 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.305); catalogued as rs779437381; called by muse, mutect2, varscan2
- SCN10A | c.194A>C p.K65T | Missense Mutation (SNP) | VAF 57/480 reads (12%) | SIFT tolerated (0.63); PolyPhen benign (0.145); catalogued as COSV101479264, COSV71860944, COSV71862775; called by muse, mutect2, varscan2
- SCN7A | c.601T>G p.F201V | Missense Mutation (SNP) | VAF 48/198 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.138); catalogued as COSV69270343; called by muse, mutect2, varscan2
- SGCD | c.224G>A p.G75D (on ENST00000435422 / NM_001128209.2; = p.G76D on NM_000337.5) | Missense Mutation (SNP) | VAF 22/184 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61905125; called by muse, mutect2, varscan2
- SLC9A3 | c.1092G>A p.W364* | Nonsense Mutation (SNP) | VAF 24/530 reads (5%) | catalogued as COSV99077931; called by muse, mutect2
- SORCS3 | c.2494C>T p.R832W | Missense Mutation (SNP) | VAF 42/409 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as rs766458554, COSV63795461; called by muse, mutect2, varscan2
- SPTA1 | c.1901A>C p.K634T | Missense Mutation (SNP) | VAF 89/370 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.263); catalogued as COSV63752423, COSV63761847; called by muse, mutect2, varscan2
- SRCAP | c.1913A>G p.N638S | Missense Mutation (SNP) | VAF 79/348 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.268); catalogued as rs766829283; called by muse, mutect2, varscan2
- SYT12 | c.706C>T p.R236W | Missense Mutation (SNP) | VAF 91/416 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.022); catalogued as rs201594640, COSV67353703; called by muse, mutect2, varscan2
- TACR3 | c.530C>T p.T177M | Missense Mutation (SNP) | VAF 52/244 reads (21%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.872); catalogued as rs777243337, CM1210494, COSV59197805; called by muse, varscan2
- TAF3 | c.1689G>C p.E563D | Missense Mutation (SNP) | VAF 36/279 reads (13%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0.003); catalogued as rs1259745454; called by muse, mutect2, varscan2
- TBC1D25 | c.484G>A p.A162T | Missense Mutation (SNP) | VAF 147/245 reads (60%) | SIFT tolerated (0.09); PolyPhen benign (0.099); catalogued as rs781841319; called by muse, mutect2, varscan2
- TCF4 | c.153A>C p.E51D | Missense Mutation (SNP) | VAF 64/278 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as COSV61894836; called by muse, mutect2, varscan2
- THBS4 | c.755G>A p.R252Q | Missense Mutation (SNP) | VAF 32/256 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs369507698, COSV63469127; called by muse, mutect2, varscan2
- TMEM201 | c.1682C>T p.S561L | Missense Mutation (SNP) | VAF 118/480 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs1390591100, COSV61160823; called by muse, mutect2, varscan2
- TMEM248 | c.727A>G p.I243V | Missense Mutation (SNP) | VAF 82/432 reads (19%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs1230784720; called by muse, varscan2
- TTC30B | c.1050T>G p.I350M | Missense Mutation (SNP) | VAF 88/404 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.139); catalogued as rs574737483; called by muse, mutect2, varscan2
- TTC30B | c.1049T>C p.I350T | Missense Mutation (SNP) | VAF 83/398 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs540477010; called by muse, mutect2, varscan2
- TTN | c.73700G>A p.G24567E (on ENST00000591111; = p.G17143E on NM_003319.4) | Missense Mutation (SNP) | VAF 32/390 reads (8%) | PolyPhen probably damaging (1); catalogued as rs778591122; called by muse, mutect2
- TTN | c.67771A>C p.T22591P (on ENST00000591111; = p.T15167P on NM_003319.4) | Missense Mutation (SNP) | VAF 81/319 reads (25%) | PolyPhen probably damaging (0.998); catalogued as COSV60132601; called by muse, varscan2
- UMOD | c.230G>T p.C77F | Missense Mutation (SNP) | VAF 42/495 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM032038; called by muse, mutect2
- UNC13C | c.2602A>T p.T868S | Missense Mutation (SNP) | VAF 36/406 reads (9%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV52850936; called by muse, mutect2
- USH1G | c.818G>A p.R273Q | Missense Mutation (SNP) | VAF 158/506 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.033); catalogued as rs763109178, COSV100140404, COSV58884019; called by muse, mutect2, varscan2
- WDR17 | c.866C>T p.S289F | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.216); catalogued as COSV54569251; called by muse, mutect2, varscan2
- WDR49 | c.1016T>G p.L339R (on ENST00000308378 / NM_001366158.1; = p.L680R on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 69/288 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.125); catalogued as COSV57702238; called by muse, mutect2, varscan2
- ZFHX3 | c.9247C>T p.R3083W | Missense Mutation (SNP) | VAF 95/338 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs769133893, COSV51720669; called by muse, mutect2, varscan2
- ZNF37A | c.631G>A p.E211K | Missense Mutation (SNP) | VAF 36/305 reads (12%) | SIFT tolerated (0.51); PolyPhen benign (0.14); catalogued as COSV61074612; called by muse, mutect2, varscan2
- ZNF668 | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 122/440 reads (28%) | SIFT tolerated (0.36); PolyPhen benign (0.084); catalogued as rs746759162; called by muse, mutect2, varscan2
- ABCA13 | c.10640C>G p.P3547R | Missense Mutation (SNP) | VAF 16/402 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ADAM2 | c.821A>G p.K274R | Missense Mutation (SNP) | VAF 22/319 reads (7%) | SIFT tolerated (0.42); PolyPhen benign (0.065); called by muse, mutect2
- ADAM20 | c.1373T>G p.F458C | Missense Mutation (SNP) | VAF 82/290 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by mutect2, varscan2
- ADAMTS16 | c.1388C>A p.A463E | Missense Mutation (SNP) | VAF 109/307 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADGRG4 | c.8920T>C p.F2974L | Missense Mutation (SNP) | VAF 20/140 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- ADGRV1 | c.4898C>A p.T1633N | Missense Mutation (SNP) | VAF 51/284 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- AHNAK | c.15317C>A p.A5106D | Missense Mutation (SNP) | VAF 98/387 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AKAP13 | c.4273G>C p.E1425Q | Missense Mutation (SNP) | VAF 83/291 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- AL117339.4 | c.326A>C p.K109T | Missense Mutation (SNP) | VAF 35/341 reads (10%) | SIFT tolerated (1); called by muse, mutect2, varscan2
- AL391650.1 | c.95G>A p.G32E | Missense Mutation (SNP) | VAF 49/592 reads (8%) | SIFT tolerated, low confidence (0.3); PolyPhen probably damaging (0.988); called by muse, mutect2
- ANKLE2 | c.2306C>G p.A769G | Missense Mutation (SNP) | VAF 134/430 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- ARHGEF4 | c.1715C>G p.A572G | Missense Mutation (SNP) | VAF 115/426 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.66); called by muse, mutect2, varscan2
- ARMC10 | c.88G>A p.G30S | Missense Mutation (SNP) | VAF 38/419 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.084); called by muse, mutect2
- ARMC2 | c.835G>T p.E279* | Nonsense Mutation (SNP) | VAF 18/158 reads (11%) | called by mutect2, varscan2
- BEND5 | c.187G>A p.A63T | Missense Mutation (SNP) | VAF 50/287 reads (17%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BHLHE23 | c.284C>T p.P95L (on ENST00000370346; = p.P111L on NM_080606.4) | Missense Mutation (SNP) | VAF 53/357 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- C10orf90 | c.1607A>G p.E536G | Missense Mutation (SNP) | VAF 54/492 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- C22orf39 | c.16G>A p.G6S | Missense Mutation (SNP) | VAF 74/215 reads (34%) | SIFT tolerated (0.91); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CADPS | c.1031A>G p.K344R | Missense Mutation (SNP) | VAF 34/400 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- CALCR | c.251A>G p.D84G | Missense Mutation (SNP) | VAF 68/255 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- CAPN11 | c.449C>T p.T150I | Missense Mutation (SNP) | VAF 57/332 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- CCDC88B | c.3692T>C p.L1231S | Missense Mutation (SNP) | VAF 88/312 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- CEACAM4 | c.520C>A p.L174M | Missense Mutation (SNP) | VAF 79/340 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- CFAP298-TCP10L | c.420A>C p.K140N | Missense Mutation (SNP) | VAF 60/340 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- CFAP65 | c.1561G>T p.G521C | Missense Mutation (SNP) | VAF 130/464 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CHMP1A | c.274G>A p.V92M | Missense Mutation (SNP) | VAF 65/238 reads (27%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- CMTR2 | c.2180T>A p.M727K | Missense Mutation (SNP) | VAF 96/326 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by mutect2, varscan2
- CNTNAP5 | c.2669T>A p.V890E | Missense Mutation (SNP) | VAF 31/326 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL6A2 | c.644A>C p.D215A | Missense Mutation (SNP) | VAF 60/468 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- COL6A6 | c.1912T>G p.F638V | Missense Mutation (SNP) | VAF 97/371 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- COP1 | c.755T>C p.L252P | Missense Mutation (SNP) | VAF 44/205 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- COPB1 | c.1100_1101del p.T367Kfs*2 | Frame Shift Del (DEL) | VAF 69/280 reads (25%) | called by mutect2, pindel, varscan2
- CSF1 | c.811G>A p.D271N | Missense Mutation (SNP) | VAF 125/405 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- CSTF2T | c.1333A>C p.T445P | Missense Mutation (SNP) | VAF 121/409 reads (30%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- CTAGE9 | c.186T>G p.S62R | Missense Mutation (SNP) | VAF 55/426 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- DNAH5 | c.11537A>G p.Q3846R | Missense Mutation (SNP) | VAF 61/222 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DNAH9 | c.10304T>G p.V3435G | Missense Mutation (SNP) | VAF 41/389 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- DOP1B | c.1762G>T p.D588Y | Missense Mutation (SNP) | VAF 143/422 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DPPA4 | c.86A>T p.D29V | Missense Mutation (SNP) | VAF 70/270 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.221); called by muse, mutect2, varscan2
- DYNC1H1 | c.2444T>C p.L815P | Missense Mutation (SNP) | VAF 101/338 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- ENDOV | c.731G>A p.R244Q | Missense Mutation (SNP) | VAF 45/379 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- ENPEP | c.2254G>C p.A752P | Missense Mutation (SNP) | VAF 75/280 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ENPP3 | c.1080T>G p.N360K | Missense Mutation (SNP) | VAF 33/250 reads (13%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- EPHB1 | c.1993T>C p.F665L | Missense Mutation (SNP) | VAF 34/424 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2
- ESR1 | c.629A>C p.K210T | Missense Mutation (SNP) | VAF 16/270 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- EVC | c.2916A>C p.Q972H | Missense Mutation (SNP) | VAF 64/259 reads (25%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.693); called by muse, mutect2, varscan2
- FOXL2NB | c.437G>A p.R146Q | Missense Mutation (SNP) | VAF 153/504 reads (30%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.1657A>G p.T553A | Missense Mutation (SNP) | VAF 52/151 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- FRMD3 | c.1567C>A p.P523T | Missense Mutation (SNP) | VAF 113/406 reads (28%) | SIFT tolerated (0.48); PolyPhen benign (0.003); called by mutect2, varscan2
- G6PC | c.337C>T p.P113S | Missense Mutation (SNP) | VAF 55/226 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GPR141 | c.393T>G p.H131Q | Missense Mutation (SNP) | VAF 45/554 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- GPR149 | c.1076C>A p.P359Q | Missense Mutation (SNP) | VAF 90/303 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- GPR158 | c.2151G>T p.E717D | Missense Mutation (SNP) | VAF 14/218 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GRM3 | c.1777A>G p.M593V | Missense Mutation (SNP) | VAF 78/383 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- HPSE2 | c.976A>C p.S326R | Missense Mutation (SNP) | VAF 48/354 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- HRNR | c.2125C>A p.Q709K | Missense Mutation (SNP) | VAF 186/588 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- HRNR | c.327A>C p.Q109H | Missense Mutation (SNP) | VAF 34/604 reads (6%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); called by muse, mutect2
- IP6K2 | c.605-2_610dup p.I204Kfs*9 | Frame Shift Ins (INS) | VAF 46/215 reads (21%) | called by mutect2, varscan2
- IQCH | c.571C>T p.P191S | Missense Mutation (SNP) | VAF 64/243 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.227); called by muse, mutect2, varscan2
- ITPRID1 | c.2660A>T p.H887L | Missense Mutation (SNP) | VAF 16/362 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2
- JAK3 | c.1348C>G p.L450V | Missense Mutation (SNP) | VAF 95/383 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- KBTBD2 | c.972A>C p.Q324H | Missense Mutation (SNP) | VAF 69/334 reads (21%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- KIDINS220 | c.1030A>C p.K344Q | Missense Mutation (SNP) | VAF 88/333 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KIF5B | c.2578C>G p.L860V | Missense Mutation (SNP) | VAF 38/372 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.356); called by muse, mutect2, varscan2
- KMT2D | c.14471C>T p.A4824V | Missense Mutation (SNP) | VAF 51/438 reads (12%) | SIFT tolerated (0.5); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- KREMEN2 | c.931_942del p.D311_G314del | In Frame Del (DEL) | VAF 86/372 reads (23%) | called by mutect2, varscan2
- LRP12 | c.1336A>C p.K446Q | Missense Mutation (SNP) | VAF 89/402 reads (22%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- LRRIQ3 | c.1445G>T p.S482I | Missense Mutation (SNP) | VAF 21/192 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- LRRTM4 | c.428A>T p.N143I | Missense Mutation (SNP) | VAF 86/346 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LTK | c.1535T>G p.L512R | Missense Mutation (SNP) | VAF 76/276 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MAB21L1 | c.1030C>T p.R344* | Nonsense Mutation (SNP) | VAF 61/295 reads (21%) | called by muse, mutect2, varscan2
- MAP1B | c.222C>G p.N74K | Missense Mutation (SNP) | VAF 38/200 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MAP2 | c.3767A>G p.Q1256R | Missense Mutation (SNP) | VAF 104/398 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- MBD1 | c.227C>A p.A76D | Missense Mutation (SNP) | VAF 45/246 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.464); called by muse, mutect2, varscan2
- MCF2 | c.1873G>C p.D625H | Missense Mutation (SNP) | VAF 31/128 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MRPL58 | c.142C>T p.L48F | Missense Mutation (SNP) | VAF 99/321 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.818); called by muse, mutect2, varscan2
- MTCL1 | c.3982T>A p.S1328T (on ENST00000306329 / NM_001378206.1; = p.S1009T on NM_015210.4) | Missense Mutation (SNP) | VAF 56/880 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.627); called by muse, mutect2
- MUC16 | c.11875A>C p.S3959R | Missense Mutation (SNP) | VAF 87/388 reads (22%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.076); called by muse, mutect2
- MUC5B | c.14729C>T p.P4910L | Missense Mutation (SNP) | VAF 146/478 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.078); called by muse, varscan2
- NAPSA | c.110G>T p.G37V | Missense Mutation (SNP) | VAF 35/259 reads (14%) | SIFT tolerated (0.44); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- NBAS | c.2721G>T p.Q907H | Missense Mutation (SNP) | VAF 74/275 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- NECAB1 | c.938G>A p.S313N | Missense Mutation (SNP) | VAF 84/258 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NINL | c.188T>C p.F63S | Missense Mutation (SNP) | VAF 46/250 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NLGN4Y | c.1195G>A p.V399M | Missense Mutation (SNP) | VAF 54/157 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); called by muse, mutect2, varscan2
- NLRC4 | c.128G>T p.C43F | Missense Mutation (SNP) | VAF 107/387 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.609); called by muse, mutect2, varscan2
- NLRP2 | c.616T>A p.S206T | Missense Mutation (SNP) | VAF 201/657 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.286); called by muse, mutect2, varscan2
- NLRP9 | c.920T>A p.F307Y | Missense Mutation (SNP) | VAF 91/383 reads (24%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- NOTCH1 | c.3402G>C p.Q1134H | Missense Mutation (SNP) | VAF 157/519 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NRCAM | c.3051T>A p.N1017K (on ENST00000379028 / NM_001371124.1; = p.N1001K on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/353 reads (5%) | SIFT tolerated (0.47); PolyPhen benign (0.106); called by muse, mutect2
- NUDT12 | c.1301G>T p.G434V | Missense Mutation (SNP) | VAF 41/214 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- NXPE2 | c.898T>G p.F300V | Missense Mutation (SNP) | VAF 74/321 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.356); called by muse, mutect2, varscan2
- OR13C5 | c.442T>C p.S148P | Missense Mutation (SNP) | VAF 100/341 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.568); called by muse, mutect2, varscan2
- OR1I1 | c.815A>C p.K272T | Missense Mutation (SNP) | VAF 100/380 reads (26%) | SIFT tolerated (0.74); PolyPhen probably damaging (1); called by muse, varscan2
- OR1L6 | c.145T>G p.F49V (on ENST00000373684; = p.F13V on NM_001004453.2) | Missense Mutation (SNP) | VAF 71/301 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.322); called by muse, mutect2, varscan2
- OR2T33 | c.643T>A p.S215T | Missense Mutation (SNP) | VAF 22/429 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.344); called by muse, mutect2
- OR4K2 | c.89T>G p.V30G | Missense Mutation (SNP) | VAF 44/421 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- OR6T1 | c.884A>G p.D295G | Missense Mutation (SNP) | VAF 162/401 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.045); called by muse, varscan2
- OTOP1 | c.658A>C p.N220H | Missense Mutation (SNP) | VAF 80/258 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- PAPPA | c.1814C>T p.P605L | Missense Mutation (SNP) | VAF 93/329 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCLO | c.557A>T p.Q186L | Missense Mutation (SNP) | VAF 91/397 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.52); called by muse, mutect2, varscan2
- PDE3A | c.256G>A p.G86S | Missense Mutation (SNP) | VAF 183/610 reads (30%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PDLIM5 | c.1294T>G p.L432V | Missense Mutation (SNP) | VAF 63/257 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- PDZRN4 | c.1581G>T p.E527D (on ENST00000402685 / NM_001164595.2; = p.E269D on NM_013377.4) | Missense Mutation (SNP) | VAF 52/188 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- PIEZO1 | c.1996C>A p.Q666K | Missense Mutation (SNP) | VAF 76/261 reads (29%) | SIFT tolerated (0.75); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PLCB2 | c.1019C>T p.S340F | Missense Mutation (SNP) | VAF 87/317 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PTPN13 | c.3108G>T p.R1036S | Missense Mutation (SNP) | VAF 25/304 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.052); called by muse, mutect2
- PXDN | c.2262del p.M755Cfs*6 | Frame Shift Del (DEL) | VAF 64/338 reads (19%) | called by mutect2, varscan2
- RANBP17 | c.2369C>A p.S790Y | Missense Mutation (SNP) | VAF 43/167 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RASAL1 | c.1312C>T p.R438C | Missense Mutation (SNP) | VAF 169/506 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- RER1 | c.366-3A>G | Splice Region (SNP) | VAF 54/434 reads (12%) | called by muse, mutect2, varscan2
- RIOX2 | c.176G>T p.W59L | Missense Mutation (SNP) | VAF 42/379 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RNF150 | c.421T>A p.S141T | Missense Mutation (SNP) | VAF 27/412 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.401); called by muse, mutect2
- RUBCNL | c.914T>C p.F305S | Missense Mutation (SNP) | VAF 33/162 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- RUSC2 | c.2845C>A p.Q949K | Missense Mutation (SNP) | VAF 30/276 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.034); called by muse, mutect2
- SAMD9 | c.4329T>G p.N1443K | Missense Mutation (SNP) | VAF 46/329 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SART1 | c.1663G>A p.A555T | Missense Mutation (SNP) | VAF 56/519 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SERPINA11 | c.791T>C p.L264P | Missense Mutation (SNP) | VAF 47/497 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- SIX3 | c.58G>A p.A20T | Missense Mutation (SNP) | VAF 74/294 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.046); called by muse, varscan2
- SLC26A3 | c.105dup p.L36Sfs*9 | Frame Shift Ins (INS) | VAF 55/274 reads (20%) | called by mutect2, pindel, varscan2
- SLC4A7 | c.2069T>A p.L690Q | Missense Mutation (SNP) | VAF 42/182 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC5A12 | c.589T>G p.L197V | Missense Mutation (SNP) | VAF 104/387 reads (27%) | SIFT tolerated (0.44); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- SORCS2 | c.77C>T p.P26L | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, varscan2
- STS | c.548T>C p.L183P | Missense Mutation (SNP) | VAF 85/191 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- STT3A | c.417G>T p.K139N | Missense Mutation (SNP) | VAF 99/229 reads (43%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- SVIL | c.4745A>C p.K1582T (on ENST00000355867 / NM_021738.3; = p.K1156T on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/415 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.082); called by muse, mutect2
- SYPL2 | c.208G>T p.A70S | Missense Mutation (SNP) | VAF 38/271 reads (14%) | SIFT tolerated (0.7); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- TBX18 | c.410A>T p.Q137L | Missense Mutation (SNP) | VAF 164/501 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- TDRD15 | c.3005T>G p.V1002G | Missense Mutation (SNP) | VAF 50/180 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- TPCN1 | c.1702G>A p.A568T | Missense Mutation (SNP) | VAF 38/365 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- TPX2 | c.1794C>G p.D598E | Missense Mutation (SNP) | VAF 25/376 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.013); called by muse, mutect2
- TRAF3 | c.882G>T p.Q294H | Missense Mutation (SNP) | VAF 46/212 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.719); called by mutect2, varscan2
- TRANK1 | c.4487T>A p.L1496H | Missense Mutation (SNP) | VAF 110/395 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TRHR | c.187T>A p.Y63N | Missense Mutation (SNP) | VAF 135/432 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRIB2 | c.560A>T p.E187V | Missense Mutation (SNP) | VAF 28/186 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by mutect2, varscan2
- TRIM31 | c.912T>G p.D304E | Missense Mutation (SNP) | VAF 48/266 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- TRIML1 | c.172A>G p.R58G | Missense Mutation (SNP) | VAF 92/355 reads (26%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.457); called by muse, mutect2, varscan2
- TRPA1 | c.1660T>G p.F554V | Missense Mutation (SNP) | VAF 57/238 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.338); called by muse, mutect2, varscan2
- TTN | c.67818T>G p.D22606E (on ENST00000591111; = p.D15182E on NM_003319.4) | Missense Mutation (SNP) | VAF 87/286 reads (30%) | PolyPhen benign (0.003); called by muse, varscan2
- TYK2 | c.508C>G p.L170V | Missense Mutation (SNP) | VAF 40/357 reads (11%) | SIFT tolerated (0.88); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- UBFD1 | c.819G>A p.M273I | Missense Mutation (SNP) | VAF 73/198 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- USH2A | c.6983C>T p.P2328L | Missense Mutation (SNP) | VAF 26/247 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.563); called by muse, mutect2, varscan2
- VAT1L | c.1013T>A p.L338H | Missense Mutation (SNP) | VAF 111/388 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- VPS13C | c.8208C>A p.F2736L (on ENST00000644861 / NM_020821.3; = p.F2693L on NM_017684.5) | Missense Mutation (SNP) | VAF 93/350 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- WDFY4 | c.4472T>G p.L1491R | Missense Mutation (SNP) | VAF 37/422 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); called by muse, mutect2
- WDFY4 | c.5651A>G p.E1884G | Missense Mutation (SNP) | VAF 60/424 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- WDR17 | c.328A>G p.I110V | Missense Mutation (SNP) | VAF 38/161 reads (24%) | SIFT tolerated (0.65); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- XIRP2 | c.184C>A p.L62M | Missense Mutation (SNP) | VAF 91/364 reads (25%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- ZIC4 | c.68C>A p.S23* | Nonsense Mutation (SNP) | VAF 59/210 reads (28%) | called by muse, mutect2, varscan2
- ZMYM6 | c.2171dup p.N724Kfs*2 | Frame Shift Ins (INS) | VAF 38/154 reads (25%) | called by mutect2, varscan2
- ZNF208 | c.1055A>C p.K352T | Missense Mutation (SNP) | VAF 53/239 reads (22%) | SIFT tolerated (0.42); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- ZNF3 | c.814A>G p.I272V | Missense Mutation (SNP) | VAF 79/505 reads (16%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- ZNF3 | c.493A>G p.T165A | Missense Mutation (SNP) | VAF 106/512 reads (21%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF316 | c.1969G>A p.G657R | Missense Mutation (SNP) | VAF 58/203 reads (29%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- ZNF615 | c.1809G>C p.K603N | Missense Mutation (SNP) | VAF 133/457 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ZNF844 | c.599A>C p.K200T | Missense Mutation (SNP) | VAF 87/290 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- ADAMTS20 | c.282C>T p.T94= | Silent (SNP) | VAF 78/381 reads (20%) | catalogued as COSV67129745, COSV67131171; called by muse, mutect2, varscan2
- ADH4 | c.66T>A p.L22= | Silent (SNP) | VAF 32/291 reads (11%) | called by muse, mutect2, varscan2
- AFAP1 | c.924C>T p.S308= | Silent (SNP) | VAF 66/257 reads (26%) | called by muse, mutect2, varscan2
- ARHGAP31 | c.3976C>T p.L1326= | Silent (SNP) | VAF 39/351 reads (11%) | called by muse, mutect2, varscan2
- ASTN1 | c.2529A>G p.A843= | Silent (SNP) | VAF 75/316 reads (24%) | called by muse, mutect2, varscan2
- ATP4B | c.561C>G p.V187= | Silent (SNP) | VAF 69/401 reads (17%) | called by muse, mutect2
- BPNT2 | c.159G>A p.A53= | Silent (SNP) | VAF 56/481 reads (12%) | catalogued as COSV52907337; called by muse, mutect2, varscan2
- CBX4 | c.264T>G p.R88= | Silent (SNP) | VAF 83/300 reads (28%) | catalogued as COSV99490554; called by muse, mutect2, varscan2
- CLEC1B | c.477C>T p.V159= | Silent (SNP) | VAF 27/298 reads (9%) | catalogued as rs377402728, COSV100046032; called by muse, mutect2
- COL3A1 | c.3147A>C p.P1049= | Silent (SNP) | VAF 36/384 reads (9%) | called by muse, mutect2
- CRAT | c.1239G>C p.V413= | Silent (SNP) | VAF 54/306 reads (18%) | called by muse, mutect2, varscan2
- CYLC1 | c.240T>C p.S80= | Silent (SNP) | VAF 68/171 reads (40%) | called by muse, mutect2, varscan2
- EIF3B | c.444G>A p.A148= | Silent (SNP) | VAF 108/273 reads (40%) | called by muse, mutect2, varscan2
- EYA1 | c.1644A>G p.K548= | Silent (SNP) | VAF 46/208 reads (22%) | catalogued as CD082107, COSV100379841; called by muse, mutect2, varscan2
- FAM171A2 | c.1686G>A p.P562= | Silent (SNP) | VAF 18/165 reads (11%) | called by muse, mutect2, varscan2
- FANCA | c.3226C>T p.L1076= | Silent (SNP) | VAF 55/251 reads (22%) | called by muse, mutect2, varscan2
- FBXO24 | c.1593G>A p.T531= (on ENST00000241071 / NM_033506.3; = p.T569= on NM_012172.5) | Silent (SNP) | VAF 127/574 reads (22%) | catalogued as rs752717605; called by muse, mutect2, varscan2
- FCRL2 | c.648G>A p.V216= | Silent (SNP) | VAF 82/352 reads (23%) | called by muse, mutect2, varscan2
- FNDC1 | c.3240C>T p.D1080= | Silent (SNP) | VAF 147/437 reads (34%) | catalogued as COSV51932037; called by muse, mutect2, varscan2
- FOXG1 | c.1218C>T p.S406= | Silent (SNP) | VAF 131/474 reads (28%) | called by muse, mutect2, varscan2
- GNGT2 | c.76A>C p.R26= | Silent (SNP) | VAF 65/301 reads (22%) | called by muse, mutect2, varscan2
- GRM6 | c.1407G>A p.R469= | Silent (SNP) | VAF 130/471 reads (28%) | catalogued as rs752683903; called by muse, mutect2
- GUCY1B1 | c.648T>C p.A216= | Silent (SNP) | VAF 28/264 reads (11%) | catalogued as rs1432499131; called by muse, mutect2, varscan2
- H2AX | c.159G>A p.A53= | Silent (SNP) | VAF 169/487 reads (35%) | catalogued as rs375920693; called by muse, mutect2, varscan2
- H2BC3 | c.360C>G p.T120= | Silent (SNP) | VAF 10/142 reads (7%) | called by muse, mutect2
- HCN2 | c.1770C>T p.S590= | Silent (SNP) | VAF 66/282 reads (23%) | catalogued as rs768523518, COSV52115447; called by muse, mutect2, varscan2
- IFT80 | c.111A>C p.I37= | Silent (SNP) | VAF 76/301 reads (25%) | called by muse, mutect2, varscan2
- IRS2 | c.3768C>T p.I1256= | Silent (SNP) | VAF 48/565 reads (8%) | called by muse, mutect2
- KRTAP2-2 | c.324C>T p.C108= | Silent (SNP) | VAF 52/174 reads (30%) | catalogued as rs1389666484; called by muse, varscan2
- KRTAP21-1 | c.132C>T p.S44= | Silent (SNP) | VAF 94/531 reads (18%) | catalogued as COSV100624905, COSV58646304; called by muse, mutect2, varscan2
- LRP1B | c.801A>C p.A267= | Silent (SNP) | VAF 31/180 reads (17%) | called by muse, mutect2, varscan2
- LRRC4B | c.1026G>A p.A342= | Silent (SNP) | VAF 61/525 reads (12%) | catalogued as COSV100976065; called by muse, mutect2, varscan2
- MAGEB1 | c.567G>T p.L189= | Silent (SNP) | VAF 63/263 reads (24%) | catalogued as COSV66776858; called by muse, mutect2, varscan2
- MAP2 | c.4902T>C p.S1634= | Silent (SNP) | VAF 125/403 reads (31%) | catalogued as COSV52282429; called by muse, mutect2, varscan2
- MIS18BP1 | c.1398T>C p.N466= | Silent (SNP) | VAF 15/122 reads (12%) | called by muse, mutect2, varscan2
- MKI67 | c.6315T>G p.S2105= | Silent (SNP) | VAF 75/517 reads (15%) | called by muse, mutect2, varscan2
- MRPL19 | c.96C>T p.I32= | Silent (SNP) | VAF 34/345 reads (10%) | catalogued as rs1209342919; called by muse, mutect2, varscan2
- MTOR | c.1449C>T p.F483= | Silent (SNP) | VAF 99/327 reads (30%) | catalogued as rs769447576; called by muse, mutect2, varscan2
- MUC12 | c.8508A>G p.P2836= (on ENST00000379442; = p.P2693= on NM_001164462.1) | Silent (SNP) | VAF 49/1338 reads (4%) | called by muse, mutect2
- NEFM | c.1875A>G p.K625= | Silent (SNP) | VAF 147/539 reads (27%) | called by muse, varscan2
- NEK4 | c.2163A>G p.K721= | Silent (SNP) | VAF 87/382 reads (23%) | called by muse, mutect2, varscan2
- NLRP11 | c.2538C>T p.S846= | Silent (SNP) | VAF 60/239 reads (25%) | catalogued as rs114044008; called by muse, mutect2, varscan2
- NLRP3 | c.1314C>T p.T438= | Silent (SNP) | VAF 125/472 reads (26%) | catalogued as rs201210274; ClinVar: likely benign; called by muse, mutect2, varscan2
- NOS2 | c.690C>T p.H230= | Silent (SNP) | VAF 93/339 reads (27%) | catalogued as rs201569440, COSV58224292; called by muse, mutect2, varscan2
- NUP43 | c.372T>A p.P124= | Silent (SNP) | VAF 119/317 reads (38%) | called by muse, mutect2, varscan2
- OVCH1 | c.3081G>A p.P1027= | Silent (SNP) | VAF 79/304 reads (26%) | catalogued as rs370527130; called by muse, mutect2, varscan2
- PAX1 | c.465C>T p.N155= | Silent (SNP) | VAF 134/548 reads (24%) | catalogued as COSV101270359; called by muse, mutect2, varscan2
- PCLO | c.12438T>C p.S4146= | Silent (SNP) | VAF 73/341 reads (21%) | called by muse, mutect2, varscan2
- PDE3A | c.732C>T p.A244= | Silent (SNP) | VAF 99/352 reads (28%) | catalogued as rs575328659, COSV100762252; called by muse, mutect2, varscan2
- PITPNM3 | c.1239G>A p.T413= | Silent (SNP) | VAF 89/403 reads (22%) | called by muse, mutect2, varscan2
- POSTN | c.1881C>A p.L627= | Silent (SNP) | VAF 27/141 reads (19%) | catalogued as rs747574348; called by muse, mutect2, varscan2
- PPFIA1 | c.319A>C p.R107= | Silent (SNP) | VAF 98/337 reads (29%) | catalogued as COSV54132876; called by muse, mutect2, varscan2
- PRAMEF11 | c.309A>G p.Q103= | Silent (SNP) | VAF 78/354 reads (22%) | called by muse, mutect2
- PRL | c.102C>T p.G34= | Silent (SNP) | VAF 109/359 reads (30%) | catalogued as COSV60592324, COSV60593158; called by muse, mutect2, varscan2
- PRLHR | c.534C>T p.Y178= | Silent (SNP) | VAF 65/650 reads (10%) | called by muse, mutect2, varscan2
- PRXL2A | c.438G>A p.R146= | Silent (SNP) | VAF 142/304 reads (47%) | called by muse, mutect2, varscan2
- PSPH | c.333C>G p.G111= | Silent (SNP) | VAF 84/331 reads (25%) | called by muse, mutect2, varscan2
- PTPRU | c.1806C>A p.G602= | Silent (SNP) | VAF 34/303 reads (11%) | called by muse, mutect2, varscan2
- PTPRZ1 | c.381T>G p.T127= | Silent (SNP) | VAF 79/352 reads (22%) | catalogued as COSV101099124; called by muse, mutect2, varscan2
- RAB11FIP4 | c.120C>T p.R40= | Silent (SNP) | VAF 112/370 reads (30%) | catalogued as rs776402383; called by muse, mutect2, varscan2
- SALL1 | c.2262T>C p.S754= | Silent (SNP) | VAF 101/386 reads (26%) | called by muse, mutect2, varscan2
- SIPA1L2 | c.4521C>T p.S1507= | Silent (SNP) | VAF 26/490 reads (5%) | catalogued as rs762162925, COSV53384613; called by muse, mutect2
- SLC15A4 | c.1209G>A p.K403= | Silent (SNP) | VAF 102/444 reads (23%) | called by muse, mutect2
- SLC4A8 | c.2721C>A p.L907= | Silent (SNP) | VAF 32/349 reads (9%) | called by muse, mutect2
- SORCS2 | c.333C>T p.A111= | Silent (SNP) | VAF 70/322 reads (22%) | called by muse, mutect2, varscan2
- SPAG8 | c.345C>T p.P115= | Silent (SNP) | VAF 157/452 reads (35%) | catalogued as rs761021545, COSV99427818; called by muse, mutect2, varscan2
- SYT7 | c.603C>T p.N201= | Silent (SNP) | VAF 83/322 reads (26%) | catalogued as rs376575654; called by muse, mutect2, varscan2
- TGIF2LY | c.420G>A p.A140= | Silent (SNP) | VAF 49/242 reads (20%) | catalogued as rs762615553, COSV58291920; called by muse, mutect2, varscan2
- TKTL2 | c.597C>T p.G199= | Silent (SNP) | VAF 82/327 reads (25%) | catalogued as rs532776025, COSV54917391, COSV54919254; called by muse, mutect2, varscan2
- TMEM94 | c.2346C>T p.C782= | Silent (SNP) | VAF 100/345 reads (29%) | catalogued as rs779931955; called by muse, mutect2, varscan2
- TNXB | c.1506C>T p.R502= | Silent (SNP) | VAF 186/565 reads (33%) | catalogued as COSV64478237; called by muse, mutect2, varscan2
- TRIM64B | c.1299T>C p.P433= | Silent (SNP) | VAF 69/444 reads (16%) | called by muse, mutect2, varscan2
- UGGT1 | c.3006A>G p.R1002= | Silent (SNP) | VAF 84/295 reads (28%) | called by muse, mutect2, varscan2
- UHRF1 | c.1857G>A p.E619= (on ENST00000612630 / NM_001290050.1; = p.E632= on NM_013282.4) | Silent (SNP) | VAF 42/396 reads (11%) | called by muse, mutect2, varscan2
- UNC5D | c.2448G>A p.Q816= | Silent (SNP) | VAF 33/284 reads (12%) | called by muse, mutect2, varscan2
- USP43 | c.2832A>T p.P944= | Silent (SNP) | VAF 128/444 reads (29%) | called by muse, mutect2, varscan2
- WAC | c.1668G>A p.T556= | Silent (SNP) | VAF 221/468 reads (47%) | catalogued as rs781664853, COSV61568226; called by muse, mutect2, varscan2
- WDR81 | c.1347G>A p.T449= | Silent (SNP) | VAF 28/590 reads (5%) | catalogued as rs888901526, COSV58484720; called by muse, mutect2
- WWP1 | c.2319C>T p.T773= | Silent (SNP) | VAF 109/286 reads (38%) | called by muse, mutect2, varscan2
- ZFP28 | c.2532T>G p.S844= | Silent (SNP) | VAF 104/379 reads (27%) | called by muse, mutect2, varscan2
- ZNF3 | c.21C>G p.L7= | Silent (SNP) | VAF 71/355 reads (20%) | called by muse, mutect2, varscan2
- ZNF829 | c.885T>G p.P295= | Silent (SNP) | VAF 102/328 reads (31%) | catalogued as COSV66986570; called by muse, mutect2, varscan2
- AKAP7 | c.*766T>C | 3'UTR (SNP) | VAF 45/310 reads (15%) | called by muse, mutect2, varscan2
- DCHS2 | n.6989C>A | RNA (SNP) | VAF 38/321 reads (12%) | called by muse, mutect2, varscan2
- GPSM1 | c.69-2349G>A | Intron (SNP) | VAF 160/595 reads (27%) | catalogued as rs979688601; called by muse, mutect2, varscan2
- KCNQ1 | c.1393+26795T>G | Intron (SNP) | VAF 49/153 reads (32%) | called by muse, mutect2, varscan2
- MAP2 | c.5074-2056A>G | Intron (SNP) | VAF 22/379 reads (6%) | catalogued as COSV52291917; called by muse, mutect2
- PAX6 | c.1032+161T>C | Intron (SNP) | VAF 25/235 reads (11%) | called by muse, mutect2, varscan2
- PEG10 | c.*247C>T | 3'UTR (SNP) | VAF 90/394 reads (23%) | called by muse, mutect2, varscan2
- PITX2 | c.185-940A>T | Intron (SNP) | VAF 20/442 reads (5%) | called by muse, mutect2
- RGS6 | c.1368+5225T>C | Intron (SNP) | VAF 69/320 reads (22%) | called by muse, mutect2, varscan2
- SCD5 | c.569+19800G>A | Intron (SNP) | VAF 32/288 reads (11%) | catalogued as rs368631128; called by muse, mutect2, varscan2
- SLC12A1 | c.724+534A>C | Intron (SNP) | VAF 71/287 reads (25%) | called by muse, mutect2, varscan2
- SLC17A3 | c.304-201C>T | Intron (SNP) | VAF 83/258 reads (32%) | catalogued as rs755492216; called by muse, mutect2, varscan2
- TMEM8B | c.-229G>A | 5'UTR (SNP) | VAF 117/449 reads (26%) | called by muse, mutect2, varscan2
- TTN | c.10360+3480T>G | Intron (SNP) | VAF 67/272 reads (25%) | called by muse, mutect2, varscan2
- ZNF773 | chr19:57513054 C>G | 3'Flank (SNP) | VAF 82/283 reads (29%) | catalogued as rs773770787; called by muse, mutect2, varscan2
